Surgical pathology report (de-identified scan), TCGA case TCGA-CN-4735, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-CN-4735-01A (Primary Tumor).

[page 1 of 8]
PATIENT HISTORY:

CHIEF COMPLAINT/ PRE-OP/ POST-OP DIAGNOSIS: T4 N2b left pyriform.

PROCEDURE: Bilateral neck dissection and total laryngectomy.

SPECIFIC CLINICAL QUESTION: Need histology.

OUTSIDE TISSUE DIAGNOSIS: No.

PRIOR MALIGNANCY: No.

CHEMORADIATION THERAPY: No.

ORGAN TRANSPLANT: No.

IMMUNOSUPPRESSION: No.

OTHER DISEASES: No.

ADDENDA:

Addendum

Results of immunoperoxidase stains of the tumor are as follows:

EGFR – positive

P16 – negative

HPV – negative.

My signature is attestation that I have personally reviewed the submitted material(s) and the above diagnosis reflects that evaluation.

FINAL DIAGNOSIS:

PART 1: LARYNGEAL MASS, BIOPSY –
INVASIVE BASALOID SQUAMOUS CELL CARCINOMA.

PART 2: LYMPH NODE, ZONE V, BIOPSY –
ONE LYMPH NODE FREE OF TUMOR (0/1).

PART 3: LYMPH NODES, RIGHT, LEVELS II, III AND IV, NECK DISSECTION –

[page 2 of 8]
Pathology Report

- A. TWENTY-NINE LYMPH NODES FREE OF TUMOR (0/29).
- B. TWO LYMPH NODES EACH WITH A MICROSCOPIC FOCUS OF CYTOLOGICALLY BLAND THYROID, FAVOR BENIGN THYROID INCLUSIONS. (SEE COMMENT)

PART 4: LYMPH NODES, LEFT, LEVEL II, III AND IV, NECK DISSECTION –

- A. METASTATIC BASALOID SQUAMOUS CELL CARCINOMA IN FOUR OF THIRTY-NINE LYMPH NODES (4/39).
- B. NO EXTRACAPSULAR EXTENSION SEEN.
- C. SEGMENT OF SALIVARY GLAND FREE OF TUMOR.
- D. THE SPECIMEN WAS UNORIENTED AND THEREFORE THE LEVEL OF THE POSITIVE NODES CANNOT BE DETERMINED.

PART 5: LARYNX, LARYNGOPHARYNGECTOMY –

- A. INVASIVE BASALOID SQUAMOUS CELL CARCINOMA OF THE LEFT PYRIFORM SINUS WITH EXTENSION INTO THE LEFT ARYEPIGLOTTIC FOLD, PRE-EPIGLOTTIC SPACE AND LEFT PERIEPIGLOTTIC SPACE (4.1 CM).
- B. NO PERINEURAL INVASION IS SEEN.
- C. RESECTION MARGINS ARE FREE OF TUMOR (see parts 6, 7 and 8).
- D. THYROID CARTILAGE IS FREE OF TUMOR.
- E. ONE HYPERCELLULAR LEFT PARATHYROID GLAND (0.5 CM).
- F. LEFT LOBE OF THYROID WITH NO SIGNIFICANT PATHOLOGIC CHANGES.
- G. METASTATIC BASALOID SQUAMOUS CELL CARCINOMA IN ONE LEVEL VI LYMPH NODE (1/1).
- H. PATHOLOGIC STAGE: T3 N2b MX.

PART 6: RIGHT POSTERIOR CRICOID, BIOPSY –
NO TUMOR SEEN.

PART 7: LEFT INFERIOR CLOSE TO RECURRENT LARYNGEAL NERVE, BIOPSY –
NO TUMOR SEEN.

PART 8: LEFT VALLECULA, BIOPSY –
NO TUMOR SEEN.

COMMENT:

The thyroid tissue in the right cervical lymph nodes is most consistent with benign thyroid inclusions, however, I would consider clinical evaluation of the right lobe of the thyroid to ensure that it does not have a lesion. EGFR, c-MET, HPV and p16 studies have been ordered and the results will be reported in an addendum.

EB/acs

My signature is attestation that I have personally reviewed the submitted material(s) and the final diagnosis reflects that evaluation.

GROSS DESCRIPTION:

The specimen is received in eight parts.

[page 3 of 8]
Pathology Report

Part 1 is labeled with the patient's name, medical record number, initials [REDACTED] and designated "laryngeal mass." The specimen consists of tan, soft tissue fragments (1.5 x 0.7 x 0.3 cm in aggregate). The specimen is entirely submitted in one cassette labeled 1AFS.

Part 2 is labeled with the patient's name, medical record number, initials [REDACTED] and designated "zone 5 node." The specimen consists of a tan-brown lymph node (1.0 x 0.7 x 0.5 cm). The specimen is entirely submitted in one cassette labeled 2AFS.

Part 3 is labeled with the patient's name, medical record number, initials [REDACTED] and designated "right level II, III, and IV." The specimen consists of an undesignated neck dissection composed of fragments of muscle and adipose tissue (10.0 x 6.0 x 1.5 cm). Multiple potential lymph nodes are identified ranging in size from 0.1-2.4 cm.

Cassette Code:

3A -- one lymph node, bisected

3B-3E -- multiple potential lymph nodes.

Part 4 is labeled with the patient's name, medical record number, initials [REDACTED] and designated "left level II, III and IV." The specimen consists of an unoriented neck dissection composed of adipose tissue and fragments of muscle (13.0 x 7.0 x 3.5 cm). Multiple potential lymph nodes are identified ranging in size from 0.1-4.2 cm.

Cassette Code:

4A-4F -- multiple potential lymph nodes

4G-4I -- representative section of grossly positive node

4J-4K -- multiple potential lymph nodes.

Part 5 is labeled with the patient's name, initials [REDACTED] medical record number, and designated "larynx." The specimen consists of a complete laryngectomy, left thyroid lobectomy, and multiple tracheal rings (8.0 x 8.5 x 5.2 cm). A tumor is seen centered on the left pyriform sinus that undermines the mucosa of the false vocal cord focally and grossly it appears to involve the thyroid cartilage (4.1 x 2.7 x 2.0 cm).

Ink Code:

Green -- left lateral pyriform margin

Blue -- inferior pyriform margin

Orange -- superior left pyriform margin

Black -- deep.

Cassette Code:

5A -- inferior left pyriform radial margin

5B -- superior left pyriform radial margin

5C -- lateral left pyriform radial margin

5D -- anterior soft tissue margin

5E -- distal tracheal margin

5F -- tumor in relation to the pyriform sinus

5G -- left section through cords

5H -- left section through cords

5I -- right section through cords

5J -- tumor in relation to lateral pharyngeal wall

5K -- left lateral aryepiglottic fold

5L -- right lateral aryepiglottic fold

5M -- tumor in relation to pre-epiglottic space

5N -- tumor in relation to thyroid cartilage

5O -- nodules adjacent to right thyroid

5P -- representative section of the thyroid gland

5Q -- right level 6 lymph node.

[page 4 of 8]
Pathology Report

Part 6 is received fresh for intraoperative consultation labeled with the patient's name, medical record number, initials [REDACTED] and designated "right posterior cricoid". The specimen consists of tan fragments of soft tissue, 2.5 x 0.4 x 0.3 cm. The specimen is entirely submitted in one cassette labeled 6AFS.

Part 7 is received fresh for intraoperative consultation labeled with the patient's name, medical record number, initials [REDACTED] and designated "left inferior close to recurrent laryngeal nerve". The specimen consists of fragments of tan soft tissue, 2.1 x 1.5 x 0.3 cm. The specimen is entirely submitted in one cassette labeled 7AFS.

Part 8 is received fresh for intraoperative consultation labeled with the patient's name, medical record number, initials [REDACTED] and designated "left vallecula". The specimen consists of a strip of tan soft tissue, 2.0 x 0.4 x 0.2 cm. The specimen is entirely submitted in one cassette labeled 8AFS.

INTRAOPERATIVE CONSULTATION:

PART 1AFS: LARYNX, BIOPSY (frozen section) –

- A. MALIGNANT.
- B. POORLY DIFFERENTIATED CARCINOMA [REDACTED]

PART 2AFS: ZONE 5 LYMPH NODE (frozen section) –

- A. BENIGN.
- B. NO TUMOR SEEN [REDACTED]

PART 6AFS: RIGHT POSTERIOR CRICOID (frozen section) –

- A. BENIGN.
- B. NO TUMOR SEEN [REDACTED]

PART 7AFS: LEFT INFERIOR CLOSE TO RECURRENT LARYNGEAL NERVE (frozen section) –

- A. BENIGN.
- B. NO TUMOR SEEN [REDACTED]

PART 8AFS: LEFT VALLECULA (frozen section) –

- A. BENIGN.
- B. NO TUMOR SEEN [REDACTED]

MICROSCOPIC:

Microscopic examination substantiates the above diagnosis.

The following statement applies to all immunohistochemistry, insitu hybridization (ISH & FISH), molecular anatomic pathology, and immunofluorescence testing:

The testing was developed and its performance characteristics determined by the [REDACTED] Department of Pathology, as required by the [REDACTED] regulations. The testing has not been cleared or approved for the specific use by the U.S. Food and Drug Administration, but the FDA has determined such approval is not necessary for clinical use. Tissue fixation ranges from a minimum of 2 to a maximum of 84 hours.

This laboratory is certified under the Clinical Laboratory Improvement Amendments of [REDACTED] ("CLIA") as qualified to perform high-complexity clinical testing. Pursuant to the requirements of CLIA, ASR's used in this laboratory have been established and verified for accuracy and precision. Additional information about this type of test is available upon request.

[page 5 of 8]
Pathology Report

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY UPPER AERODIGESTIVE TRACT AND SALIVARY GLAND TUMORS

SPECIMEN TYPE:	Resection: Laryngopharyngectomy
TUMOR SITE:	Other: Left pyriform sinus
TUMOR SIZE:	Greatest dimension: 4.1 cm
HISTOLOGIC TYPE:	Basaloid squamous cell carcinoma
HISTOLOGIC GRADE:	G3
PATHOLOGIC STAGING (pTNM):	pT3 pN2b Number of regional lymph nodes examined: 70 Number of regional lymph nodes involved: 5 pMX
MARGINS:	Margins uninvolved by tumor
VENOUS/LYMPHATIC (LARGE/SMALL VESSEL) INVASION (V/L):	Absent
PERINEURAL INVASION:	Absent
ADDITIONAL PATHOLOGIC FINDINGS:	None identified

HISTO TISSUE SUMMARY/SLIDES REVIEWED:

Part 1: Larynx Mass

Stain/cnt	Block
H&E x 1	AFS
H&E x 1	AFS

Part 2: Zone 5 Nodes

Stain/cnt	Block
H&E x 1	AFS

Part 3: Right Level 2,3,4

Stain/cnt	Block
H&E x 1	A
H&E x 1	B
H&E x 1	C
H&E x 1	D
H&E x 1	E

Part 4: Left Level 2,3,4

Stain/cnt	Block
H&E x 1	A
H&E x 1	B
H&E x 1	C
H&E x 1	D
H&E x 1	E
H&E x 1	F
H&E x 1	G
H&E x 1	H

[page 6 of 8]
Pathology Report

H&E x 1 I
H&E x 1 J

Part 5: Larynx

Stain/cnt	Block
H&E x 1	A
H&E x 1	B
H&E x 1	C
H&E x 1	D
H&E x 1	E
ANEG x 1	F
ANEG x 1	F
ANEG x 1	F
EGFR x 1	F
EGFR x 1	F
H&E Recut x 1	F
HPV x 1	F
IHPV x 1	F
cmet x 1	F
IBNKNC x 6	F
H&E x 1	F
IISH x 2	F
P16 x 1	F
H&E x 1	G
H&E x 1	H
H&E x 1	I
H&E x 1	J
H&E x 1	K
H&E x 1	L
H&E x 1	M
H&E x 1	N
H&E x 1	O
H&E x 1	P
H&E x 1	Q
Decal x 1	(none)

Part 6: Right Post Cricoid

Stain/cnt	Block
H&E x 1	AFS

Part 7: Left Inferior Close to RLN

Stain/cnt	Block
H&E x 1	AFS

Part 8: Left Vallecula

[page 7 of 8]
[REDACTED]

Pathology Report

[REDACTED]

Stain/cnt Block
H&E x 1 AFS

ICD-9 Diagnosis Codes: {None Entered}

CONSULTING PATHOLOGIST(S): [REDACTED]

TC1

SPECIAL PROCEDURES:

In Situ Procedure

Interpretation

PROBE: LSI *EGFR/CEP7* Dual-Color Probe [REDACTED]

Cytogenetic Location: 7p12 / 7p11.1-q11.1

EGFR FISH STUDIES PERFORMED ON THE SQUAMOUS CELL CARCINOMA ARE NEGATIVE.

Number of cells analyzed: 60

Ratio *EGFR/CEP7*: 1.36

High Polysomy: 0%

SNR (signal to nucleus ratio): 1.9

Low Polysomy: 10(16.7%)

Trisomy: 1(1.7%)

Disomy: 49(81.6%)

PROBE: *c-MET/CEP7*

Cytogenetic Location: 7q31.2 / 7p11.1-q11.1

C-MET FISH STUDIES PERFORMED ON THE SQUAMOUS CELL CARCINOMA ARE NEGATIVE FOR AMPLIFICATION.

Number of cells analyzed: 60

Ratio *c-MET/CEP7*: 0.95

SNR (signal to nucleus ratio): 1.3

High Polysomy: 0%

Low Polysomy: 0%

Trisomy: 1(1.7%)

Disomy: 59(98.3%)

*RP11-163C9, CHORI, [REDACTED]

EGFR FISH analysis was manually performed and quantitatively assessed by analysis of a minimum of 60 cells using the *EGFR* SpectrumOrange and the *CEP7* SpectrumGreen probes.

C-MET FISH analysis was manually performed and quantitatively assessed by analysis of a minimum of 60 cells using the *c-MET* SpectrumOrange and the *CEP7* SpectrumGreen (centromeric) probes.

[page 8 of 8]
Pathology Report

My signature is attestation that I have personally reviewed the submitted material(s) and the above diagnosis reflects that evaluation.

Results

EGFR FISH positive:

High Polysomy: $\geq$ four gene copies in $\geq$ 40% of cells

Gene Amplification: Ratio gene/chromosome more than two or $\geq$ 15 gene copies in $\geq$ 10% of cells

EGFR FISH negative:

Disomy: $\leq$ two gene copies in more than 90% of the cells

Trisomy: three gene copies in more than 10% of cells

Low Polysomy: $\geq$ four gene copies in more than 10% but less than 40% of cells

c-MET FISH positive:

Gene Amplification: Ratio gene/chromosome more than two or $\geq$ 15 gene copies in $\geq$ 10% of cells

c-MET FISH negative:

Ratio gene/chromosome less than two or $\leq$ 15 gene copies in $\leq$ 10% of the cells.

Source: NCI Genomic Data Commons file 8aaadad4-f03d-4879-8bbc-54f76f3ab9bb (TCGA-CN-4735.CDCE41A4-EB0E-404E-8891-1D21E5ABD47F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).